Gene-level copy-number profile of tumor specimen TCGA-A6-5661-01B from TCGA case TCGA-A6-5661, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 80.6 years (29,446 days).
Specimen TCGA-A6-5661-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.81a4f8c8-f77b-4ae6-b720-e8e925f84405.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-5661-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 351 have no estimate.
https://portal.gdc.cancer.gov/files/3b2286ef-c88f-444a-b609-507e5a1389d9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 562; copy number 2: 59,601; copy number 3: 17; copy number 4: 61; copy number 5: 12; copy number 6: 1; copy number 7: 17; copy number 12: 1.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-5661-01A-01D-1649-01): tumor purity 0.66, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 27 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:189,132,350–189,133,292, 1 gene, copy number 5: GAPDHP75.
- chr1:204,562,413–204,562,521, 1 gene, copy number 5: RNA5SP74.
- chr4:68,614,419–68,712,498, 5 genes, copy number 5: AC147055.2, AC147055.4, AC147055.3, UGT2B15, AC147055.1.
- chr5:140,175,156–140,282,052, 2 genes, copy number 7 (within-gene range 2–7): CYSTM1, AC011379.1.
- chr8:1,565,509–1,622,417, 1 gene, copy number 5 (within-gene range 1–5): DLGAP2-AS1.
- chr9:103,999,755–104,000,469, 1 gene, copy number 6: AL590381.1.
- chr11:93,286,629–93,288,903, 1 gene, copy number 7: AP003969.2.
- chr14:36,298,564–36,320,637, 1 gene, copy number 12 (within-gene range 2–12): MBIP.
- chr15:25,054,210–25,081,378, 14 genes, copy number 7: SNORD116-2, SNORD116-3, SNORD116-4, SNORD116-5, SNORD116-6, SNORD116-7, SNORD116-8, SNORD116-9, SNORD116-10, SNORD116-11, SNORD116-12, SNORD116-13, SNORD116-14, SNORD116-15.

Autosomal genes at a single copy (total copy number 1): 38. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
